Somatic mutation profile of tumor specimen 0DW42H from CCDI case PBCNLV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (840 days).
Specimen 0DW42H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53ec72b2-8f61-4dd4-b080-603f8876dde2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW41O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8e96e2d-726e-434e-8e78-b25852f464d9

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Frame Shift Del 2, 3'UTR 2, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLFN11 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs777285142, COSV57697771, COSV57697775; called by muse, mutect2, varscan2
- ABCD3 | c.147+1G>A p.X49_splice | Splice Site (SNP) | VAF 94/283 reads (33%) | called by muse, mutect2, varscan2
- CEP350 | c.6925A>C p.N2309H | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.459); called by muse, mutect2
- NEU1 | c.1162del p.Q388Sfs*100 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by mutect2, varscan2
- SMARCB1 | c.1006del p.A336Pfs*101 (on ENST00000263121; = p.A382Pfs*101 on NM_003073.5) | Frame Shift Del (DEL) | VAF 59/95 reads (62%) | called by mutect2, varscan2
- GABRE | c.204G>T p.L68= | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as COSV64821400; called by muse, varscan2
- NEBL | c.2055+52T>A | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, varscan2
- NPDC1 | c.*57C>A | 3'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- UPP1 | c.*3G>A | 3'UTR (SNP) | VAF 54/152 reads (36%) | catalogued as rs757954560; called by muse, mutect2, varscan2
- ZNF24 | c.569-67A>T | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, varscan2
- ZNF277 | c.801+32A>T | Intron (SNP) | VAF 18/194 reads (9%) | called by muse, varscan2
